Somatic mutation profile of cancer-model specimen HCM-BROD-1127-C15-85B (3D Organoid, passage 5; aliquot HCM-BROD-1127-C15-85B-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-BROD-1127-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 45.4 years (16,577 days).
Specimen HCM-BROD-1127-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 462aeef4-3562-41f3-8e14-65b95dc7b13a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1127-C15-10A (Blood Derived Normal), aliquot HCM-BROD-1127-C15-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e773e17f-0092-44ce-bac8-c37cb7d608d3

The open-access MAF lists 195 somatic variants for this specimen: 142 protein-altering or splice-affecting, 40 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 40, Nonsense Mutation 12, Frame Shift Del 5, Intron 5, 5'UTR 3, In Frame Del 3, 3'UTR 2, Frame Shift Ins 1, RNA 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 437/438 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1101T>A p.N367K (on ENST00000272895 / NM_173076.3; = p.N49K on NM_015657.3) | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.182); catalogued as COSV55967253; called by muse, mutect2, varscan2
- ADAM11 | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 176/494 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1037353307, COSV52344942; called by muse, mutect2, varscan2
- ASB15 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754308297, COSV51929740; called by muse, mutect2, varscan2
- ASIC2 | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 395/710 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs201100877; called by muse, mutect2, varscan2
- ATG2B | c.2284C>T p.R762* | Nonsense Mutation (SNP) | VAF 290/626 reads (46%) | catalogued as COSV100737603; called by muse, mutect2, varscan2
- ATP8A2 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 141/371 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768658033, COSV54934667; called by muse, mutect2, varscan2
- BAHCC1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 414/1092 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as rs1555645702; called by muse, mutect2, varscan2
- BET1L | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 123/359 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs774740235; called by muse, mutect2, varscan2
- C6 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs918435964, COSV54710147; called by muse, mutect2, varscan2
- CDR2L | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 204/1134 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as rs1371947303, COSV61500650; called by muse, mutect2, varscan2
- CIT | c.3859C>T p.R1287W | Missense Mutation (SNP) | VAF 162/326 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs753571919, COSV55866851; called by muse, varscan2
- COL22A1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 183/372 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100277277; called by muse, mutect2, varscan2
- COL4A4 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 178/260 reads (68%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV61634080; called by mutect2, varscan2
- CSMD3 | c.3158del p.N1053Tfs*39 (on ENST00000297405 / NM_001363185.1; = p.N949Tfs*39 on NM_052900.3) | Frame Shift Del (DEL) | VAF 79/351 reads (23%) | catalogued as rs1465694861, COSV52349441; called by mutect2, pindel, varscan2
- CUL5 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 119/179 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV63230148; called by muse, mutect2, varscan2
- DNAH17 | c.9095C>T p.A3032V | Missense Mutation (SNP) | VAF 358/670 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.127); catalogued as rs778520613; called by muse, mutect2, varscan2
- ERCC2 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 130/400 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as rs777095373, COSV55544483; called by muse, mutect2, varscan2
- FAM20A | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 305/500 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1279417191, COSV101646487; called by muse, mutect2, varscan2
- FCGR3A | c.101G>A p.W34* | Nonsense Mutation (SNP) | VAF 138/512 reads (27%) | catalogued as COSV63460733; called by muse, mutect2, varscan2
- FMN2 | c.5045T>C p.L1682P | Missense Mutation (SNP) | VAF 53/441 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV60419417, COSV60456884; called by muse, mutect2, varscan2
- FSHR | c.2052C>G p.Y684* | Nonsense Mutation (SNP) | VAF 61/210 reads (29%) | catalogued as COSV58623625; called by muse, mutect2, varscan2
- GRK1 | c.1338C>A p.C446* | Nonsense Mutation (SNP) | VAF 469/781 reads (60%) | catalogued as rs758658855; called by muse, mutect2, varscan2
- HECTD2 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs777771105; called by muse, mutect2, varscan2
- HSP90AB1 | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 117/490 reads (24%) | catalogued as rs750510295; called by muse, mutect2, varscan2
- HSPA8 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 114/547 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.094); catalogued as rs1180559000; called by muse, mutect2, varscan2
- IGHV3OR16-9 | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 89/407 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as COSV61211762; called by muse, mutect2, varscan2
- INSYN1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 54/814 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as rs942540767, COSV65837581; called by muse, mutect2
- ITGAX | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 82/317 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as rs768415660; called by muse, varscan2
- LAMA1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 140/641 reads (22%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.87); catalogued as rs375547281; called by muse, mutect2, varscan2
- LRP1B | c.8243G>A p.G2748E | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV67276407; called by muse, mutect2, varscan2
- LTBP4 | c.3052G>A p.G1018R (on ENST00000308370 / NM_001042544.1; = p.G981R on NM_003573.2) | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs758824507; called by muse, varscan2
- MICALL1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 432/626 reads (69%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs768310468, COSV104394962; called by muse, varscan2
- MID2 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 82/82 reads (100%) | catalogued as COSV99464652; called by muse, varscan2
- MUC16 | c.4000A>G p.S1334G | Missense Mutation (SNP) | VAF 107/266 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV101199725, COSV67489104; called by muse, mutect2, varscan2
- MYO1F | c.1667C>A p.P556H | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100596979; called by muse, mutect2
- NBPF3 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 161/213 reads (76%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs764883298, COSV100559159; called by muse, mutect2
- NRXN2 | c.4982G>A p.R1661H | Missense Mutation (SNP) | VAF 171/518 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs985928467, COSV99634110; called by muse, varscan2
- NXPE4 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV64943924; called by muse, mutect2, varscan2
- OR2AK2 | c.540A>C p.E180D | Missense Mutation (SNP) | VAF 116/1053 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.198); catalogued as COSV63547689, COSV63557042; called by muse, mutect2, varscan2
- OR4M1 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 122/293 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV100271525; called by muse, mutect2, varscan2
- PAQR6 | c.328del p.R110Afs*110 (on ENST00000292291 / NM_001272108.2; = p.R4Afs*110 on NM_024897.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 416/1086 reads (38%) | catalogued as COSV52745613; called by mutect2, varscan2
- PCDH8 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 185/637 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100131148, COSV58813861; called by muse, mutect2, varscan2
- PDE2A | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 136/413 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as rs1239267992; called by muse, mutect2, varscan2
- PLA2G2E | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 511/702 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs773178642; called by muse, mutect2, varscan2
- PLIN3 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 184/346 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs760142638; called by muse, mutect2, varscan2
- PTPN13 | c.3588G>T p.M1196I (on ENST00000411767 / NM_080683.3; = p.M1177I on NM_006264.3) | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57415033; called by muse, mutect2, varscan2
- RDH8 | c.346G>A p.V116M (on ENST00000651512; = p.V96M on NM_015725.4) | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.882); catalogued as rs1020520832, COSV50673956; called by muse, mutect2, varscan2
- RERE | c.2557G>A p.G853S | Missense Mutation (SNP) | VAF 635/1054 reads (60%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.104); catalogued as rs1297285666; called by muse, varscan2
- RRP15 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 145/383 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1236928043, COSV100860822; called by muse, mutect2, varscan2
- SCRT2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 188/600 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs1403157294; called by muse, mutect2, varscan2
- SI | c.5214C>A p.D1738E | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV52264408, COSV52288779; called by muse, mutect2, varscan2
- SIX6 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 126/1656 reads (8%) | catalogued as COSV59801570; called by muse, mutect2
- SPATA31D4 | c.2743C>A p.L915I | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as rs1252206240; called by muse, mutect2, varscan2
- SYNE3 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 199/818 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as COSV62079991; called by muse, mutect2, varscan2
- TAFA1 | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 88/281 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV72037425; called by muse, mutect2, varscan2
- TBC1D10C | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 160/534 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs752545514, COSV56702129; called by muse, mutect2, varscan2
- TDO2 | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 82/154 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1461340796; called by mutect2, varscan2
- TGIF2LX | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs34824030; called by muse, mutect2, varscan2
- TMEM119 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 175/329 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs542172855, COSV67188469; called by muse, mutect2, varscan2
- TSHZ3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 132/280 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs772620837, COSV53674551; called by muse, mutect2, varscan2
- TSHZ3 | c.457A>T p.S153C | Missense Mutation (SNP) | VAF 178/366 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs1339954882; called by mutect2, varscan2
- TUBGCP6 | c.4048G>A p.V1350M | Missense Mutation (SNP) | VAF 140/477 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.756); catalogued as rs755040883; called by muse, mutect2, varscan2
- UBE2O | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 171/801 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs758865506; called by muse, mutect2, varscan2
- VAX2 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 164/506 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs782482672, COSV99313459; called by muse, varscan2
- VSTM4 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 297/587 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs376757983; called by muse, mutect2, varscan2
- ZFX | c.2330G>T p.R777L | Missense Mutation (SNP) | VAF 182/922 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1188549776, COSV58446665; called by muse, mutect2, varscan2
- ZNF669 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 763/1234 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs771458579, COSV100594300; called by muse, mutect2, varscan2
- ACCSL | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 105/333 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- AGAP2 | c.1553G>A p.R518K (on ENST00000547588 / NM_001122772.2; = p.R182K on NM_014770.4) | Missense Mutation (SNP) | VAF 14/504 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- AK6 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 135/267 reads (51%) | called by muse, mutect2, varscan2
- AKAP9 | c.10697C>T p.A3566V (on ENST00000359028; = p.A3542V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ANKIB1 | c.3256G>A p.V1086I | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP8B1 | c.3481G>T p.V1161F | Missense Mutation (SNP) | VAF 184/184 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- BTBD8 | c.2336T>G p.V779G (on ENST00000636805 / NM_001376131.1; = p.V266G on NM_015237.4) | Missense Mutation (SNP) | VAF 128/128 reads (100%) | SIFT tolerated (0.39); PolyPhen benign (0.315); called by muse, varscan2
- CACNA1A | c.6806G>A p.S2269N (on ENST00000614285; = p.*2267= on NM_000068.4) | Missense Mutation (SNP) | VAF 688/2844 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CAPSL | c.328A>G p.R110G | Missense Mutation (SNP) | VAF 134/374 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, varscan2
- CCDC93 | c.1379A>G p.E460G | Missense Mutation (SNP) | VAF 94/164 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CEP162 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CNTN3 | c.828G>T p.R276S | Missense Mutation (SNP) | VAF 111/555 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CRYBG3 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 87/296 reads (29%) | called by muse, mutect2, varscan2
- CSN3 | c.336C>A p.N112K | Missense Mutation (SNP) | VAF 185/499 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUBN | c.10811T>G p.I3604R | Missense Mutation (SNP) | VAF 155/298 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- D2HGDH | c.437T>A p.I146N | Missense Mutation (SNP) | VAF 140/525 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DNAH8 | c.7007A>G p.E2336G | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EMX1 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 392/620 reads (63%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVL | c.574C>T p.P192S (on ENST00000402714 / NM_001330221.2; = p.P194S on NM_016337.3) | Missense Mutation (SNP) | VAF 103/384 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FAM126B | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM91A1 | c.20_33del p.F7* | Frame Shift Del (DEL) | VAF 203/566 reads (36%) | called by mutect2, pindel, varscan2
- FCRL1 | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 98/653 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GGT1 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 143/437 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- GNL3 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 166/264 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- GOLGA6L7 | c.693G>C p.M231I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- HR | c.2555A>T p.Q852L | Missense Mutation (SNP) | VAF 204/428 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, varscan2
- IFT80 | c.1501C>A p.Q501K | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3-13 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- LINGO3 | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 198/437 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- LMBRD2 | c.303C>A p.Y101* | Nonsense Mutation (SNP) | VAF 132/357 reads (37%) | called by muse, mutect2, varscan2
- LRRC53 | c.1688C>A p.P563H | Missense Mutation (SNP) | VAF 73/370 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- LRRIQ3 | c.1122dup p.Q375Tfs*21 | Frame Shift Ins (INS) | VAF 107/262 reads (41%) | called by mutect2, pindel, varscan2
- MAST1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 160/5908 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.296); called by muse, mutect2
- MAST3 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 229/530 reads (43%) | called by muse, mutect2, varscan2
- MKI67 | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 104/382 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MORC3 | c.2676_2684del p.S894_R896del | In Frame Del (DEL) | VAF 133/237 reads (56%) | called by mutect2, pindel, varscan2
- NFIL3 | c.1139C>A p.P380H | Missense Mutation (SNP) | VAF 119/365 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NOBOX | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS1 | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 266/542 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- OAZ1 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OR10G6 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 209/440 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OSBPL9 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 110/625 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PDZRN4 | c.2652G>T p.E884D (on ENST00000402685 / NM_001164595.2; = p.E626D on NM_013377.4) | Missense Mutation (SNP) | VAF 146/329 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PHRF1 | c.4923G>C p.E1641D (on ENST00000264555 / NM_001286581.2; = p.E1640D on NM_020901.4) | Missense Mutation (SNP) | VAF 181/524 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PITPNA | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- PLS1 | c.167T>A p.V56E | Missense Mutation (SNP) | VAF 11/389 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); called by muse, mutect2
- PLXNA4 | c.659A>C p.D220A | Missense Mutation (SNP) | VAF 117/389 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- POLR1G | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 149/445 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSG3 | c.927A>C p.Q309H | Missense Mutation (SNP) | VAF 249/443 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PTX3 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.317); called by muse, mutect2
- RFX1 | c.2551C>A p.L851I | Missense Mutation (SNP) | VAF 202/3314 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- RSRP1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 283/1086 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SCN11A | c.3406A>T p.T1136S | Missense Mutation (SNP) | VAF 115/178 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC27A4 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 232/716 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC38A10 | c.1988_2010del p.P663Rfs*74 (on ENST00000374759 / NM_001037984.3; = p.P663Rfs*20 on NM_138570.4) | Frame Shift Del (DEL) | VAF 176/1382 reads (13%) | called by mutect2, pindel
- SLC5A4 | c.405_419del p.F136_R140del | In Frame Del (DEL) | VAF 83/250 reads (33%) | called by mutect2, pindel, varscan2
- SLC9C1 | c.830T>A p.L277* | Nonsense Mutation (SNP) | VAF 79/199 reads (40%) | called by muse, mutect2, varscan2
- SMAP2 | c.1141C>A p.Q381K | Missense Mutation (SNP) | VAF 108/410 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- SP1 | c.2167A>G p.T723A (on ENST00000327443 / NM_138473.3; = p.T716A on NM_003109.1) | Missense Mutation (SNP) | VAF 74/856 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.208); called by muse, mutect2
- SPSB1 | c.31A>C p.T11P | Missense Mutation (SNP) | VAF 218/598 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- SQLE | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 117/244 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SVEP1 | c.2050G>A p.V684I | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TENT4B | c.1211G>T p.G404V (on ENST00000561678 / NM_001365323.2; = p.G389V on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TG | c.3812G>T p.W1271L | Missense Mutation (SNP) | VAF 220/490 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TLN1 | c.5636C>T p.P1879L | Missense Mutation (SNP) | VAF 152/623 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TRERF1 | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 143/3512 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2
- TRIP4 | c.751del p.Q251Kfs*20 | Frame Shift Del (DEL) | VAF 238/565 reads (42%) | called by mutect2, pindel, varscan2
- UBR1 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 122/574 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- UTP23 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 332/617 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- XDH | c.802A>G p.M268V | Missense Mutation (SNP) | VAF 76/349 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- XPO6 | c.2423A>C p.Q808P | Missense Mutation (SNP) | VAF 118/463 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ZFP28 | c.2342_2356del p.G781_Y785del | In Frame Del (DEL) | VAF 183/305 reads (60%) | called by mutect2, pindel, varscan2
- ZNF439 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 185/186 reads (99%) | SIFT tolerated (0.5); PolyPhen benign (0.292); called by muse, varscan2
- ZNF780A | c.1525G>C p.A509P | Missense Mutation (SNP) | VAF 22/588 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- AJM1 | c.1338G>A p.S446= | Silent (SNP) | VAF 315/920 reads (34%) | called by muse, mutect2, varscan2
- C8orf34 | c.123A>C p.R41= | Silent (SNP) | VAF 190/797 reads (24%) | called by muse, mutect2, varscan2
- CCDC103 | c.181C>A p.R61= | Silent (SNP) | VAF 182/304 reads (60%) | catalogued as rs763938078, COSV99492986; called by muse, mutect2, varscan2
- CDH9 | c.894G>A p.G298= | Silent (SNP) | VAF 261/558 reads (47%) | called by muse, mutect2, varscan2
- CGB8 | c.108G>A p.L36= | Silent (SNP) | VAF 92/216 reads (43%) | called by mutect2, varscan2
- CHSY3 | c.363G>A p.A121= | Silent (SNP) | VAF 19/663 reads (3%) | catalogued as COSV100518964; called by muse, mutect2
- DENND10 | c.663C>T p.A221= | Silent (SNP) | VAF 106/395 reads (27%) | catalogued as rs200495809; called by muse, mutect2, varscan2
- DHX38 | c.3472C>A p.R1158= | Silent (SNP) | VAF 214/426 reads (50%) | called by muse, mutect2, varscan2
- DNAH2 | c.7698C>T p.F2566= | Silent (SNP) | VAF 343/343 reads (100%) | catalogued as rs148588175; called by muse, mutect2, varscan2
- DSPP | c.969C>A p.S323= | Silent (SNP) | VAF 85/319 reads (27%) | called by muse, mutect2, varscan2
- FANCC | c.1398C>T p.D466= | Silent (SNP) | VAF 212/621 reads (34%) | called by muse, mutect2, varscan2
- FRG2 | c.633T>G p.T211= | Silent (SNP) | VAF 123/372 reads (33%) | called by muse, mutect2, varscan2
- HSD17B13 | c.552A>C p.P184= | Silent (SNP) | VAF 86/277 reads (31%) | called by muse, mutect2, varscan2
- IMPG1 | c.531A>G p.G177= | Silent (SNP) | VAF 108/243 reads (44%) | called by muse, mutect2, varscan2
- INF2 | c.1857G>C p.V619= | Silent (SNP) | VAF 361/754 reads (48%) | called by muse, mutect2, varscan2
- LAMA1 | c.4269C>A p.G1423= | Silent (SNP) | VAF 292/403 reads (72%) | catalogued as COSV101055717, COSV67541019; called by muse, mutect2, varscan2
- LGSN | c.702C>T p.N234= | Silent (SNP) | VAF 138/344 reads (40%) | called by muse, mutect2, varscan2
- MAFA | c.414G>A p.A138= | Silent (SNP) | VAF 209/853 reads (25%) | called by muse, mutect2, varscan2
- MDGA1 | c.2856G>A p.A952= | Silent (SNP) | VAF 212/3670 reads (6%) | catalogued as rs757335830, COSV51792047; called by muse, mutect2
- MRPL52 | c.363A>G p.P121= | Silent (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- NLRX1 | c.1750C>A p.R584= | Silent (SNP) | VAF 217/355 reads (61%) | catalogued as COSV52703995; called by muse, mutect2, varscan2
- NONO | c.1350T>C p.T450= | Silent (SNP) | VAF 21/431 reads (5%) | called by muse, mutect2
- NUTM1 | c.1560C>T p.A520= | Silent (SNP) | VAF 22/465 reads (5%) | catalogued as rs750622387, COSV59215764; called by muse, mutect2
- PCDHB10 | c.969C>T p.D323= | Silent (SNP) | VAF 249/363 reads (69%) | catalogued as rs199921937; called by muse, mutect2, varscan2
- PCDHGB1 | c.1920C>T p.V640= | Silent (SNP) | VAF 322/545 reads (59%) | catalogued as rs1348613685, COSV53945529; called by muse, mutect2, varscan2
- POLD1 | c.2526C>T p.N842= | Silent (SNP) | VAF 201/591 reads (34%) | called by muse, mutect2, varscan2
- SPAG16 | c.1503C>A p.T501= | Silent (SNP) | VAF 45/271 reads (17%) | catalogued as COSV59094589; called by muse, mutect2, varscan2
- SSBP4 | c.450G>A p.P150= | Silent (SNP) | VAF 287/623 reads (46%) | catalogued as rs750575992; called by muse, mutect2, varscan2
- TAFA1 | c.241C>A p.R81= | Silent (SNP) | VAF 88/284 reads (31%) | catalogued as COSV72037141; called by muse, mutect2, varscan2
- TLX1 | c.925C>T p.L309= | Silent (SNP) | VAF 171/356 reads (48%) | called by muse, mutect2, varscan2
- TMBIM1 | c.537G>A p.T179= | Silent (SNP) | VAF 89/420 reads (21%) | catalogued as rs181300023; called by muse, mutect2, varscan2
- TMEM248 | c.918C>G p.P306= | Silent (SNP) | VAF 96/274 reads (35%) | called by muse, mutect2, varscan2
- TNRC6C | c.4896C>T p.H1632= | Silent (SNP) | VAF 504/1269 reads (40%) | called by muse, mutect2, varscan2
- TPP2 | c.426C>T p.H142= | Silent (SNP) | VAF 247/408 reads (61%) | called by muse, mutect2, varscan2
- TRRAP | c.2595C>A p.I865= | Silent (SNP) | VAF 115/348 reads (33%) | called by muse, mutect2, varscan2
- TTLL5 | c.3519C>T p.H1173= | Silent (SNP) | VAF 120/243 reads (49%) | catalogued as rs762267171; called by muse, mutect2, varscan2
- TWIST1 | c.370C>T p.L124= | Silent (SNP) | VAF 368/652 reads (56%) | catalogued as rs1563160034; called by muse, mutect2, varscan2
- VGLL2 | c.666G>A p.P222= | Silent (SNP) | VAF 390/1231 reads (32%) | called by muse, mutect2, varscan2
- ZC3H12C | c.1713G>A p.T571= | Silent (SNP) | VAF 172/270 reads (64%) | catalogued as COSV53708614; called by muse, mutect2, varscan2
- ZSWIM4 | c.612G>C p.V204= | Silent (SNP) | VAF 190/2932 reads (6%) | called by muse, mutect2
- ABI3BP | c.2008+1675C>T | Intron (SNP) | VAF 119/352 reads (34%) | called by muse, mutect2, varscan2
- AC090151.1 | chr8:54701623 C>T | 3'Flank (SNP) | VAF 253/427 reads (59%) | called by muse, mutect2, varscan2
- AKIRIN2 | c.-398_-396del | 5'UTR (DEL) | VAF 193/469 reads (41%) | called by mutect2, pindel, varscan2
- DCHS2 | n.7146C>A | RNA (SNP) | VAF 90/199 reads (45%) | catalogued as rs1351085048; called by muse, mutect2, varscan2
- FAM217A | c.-38C>T | 5'UTR (SNP) | VAF 281/281 reads (100%) | catalogued as COSV51161128; called by muse, mutect2, varscan2
- FBRS | chr16:30664314 G>A | 5'Flank (SNP) | VAF 294/463 reads (63%) | catalogued as rs1233386819; called by muse, mutect2, varscan2
- NRG1 | c.1269-467G>A | Intron (SNP) | VAF 16/290 reads (6%) | called by muse, mutect2
- NRXN1 | c.3365-109760G>T | Intron (SNP) | VAF 96/344 reads (28%) | catalogued as rs1379615629; called by muse, varscan2
- NXPH3 | c.*2322G>T | 3'UTR (SNP) | VAF 249/424 reads (59%) | called by muse, mutect2, varscan2
- PPWD1 | c.196+300C>G | Intron (SNP) | VAF 91/197 reads (46%) | called by muse, mutect2, varscan2
- SEC16B | c.1775+20G>C | Intron (SNP) | VAF 332/540 reads (61%) | called by muse, mutect2
- SLC45A4 | c.*80C>G | 3'UTR (SNP) | VAF 185/707 reads (26%) | called by muse, mutect2, varscan2
- STYX | c.-212G>C | 5'UTR (SNP) | VAF 209/2859 reads (7%) | called by muse, mutect2
